Gene-level copy-number profile of tumor specimen TCGA-SX-A71W-01A from TCGA case TCGA-SX-A71W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.0 years (24,110 days).
Specimen TCGA-SX-A71W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.55e35257-e43f-4c5a-84c1-76e4de4c2981.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SX-A71W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate.
https://portal.gdc.cancer.gov/files/4223d702-e310-4ea3-a62a-fcdabfae4d51

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,451; copy number 2: 45,709; copy number 3: 11,658.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr8:131,712,512–131,712,980, 1 gene: AC060788.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 30. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
